Somatic mutation profile of tumor specimen 0DOXGX from CCDI case PBCCXL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 16.5 years (6,024 days).
Specimen 0DOXGX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87e287a2-8c25-40f7-a405-f8b61bb1621e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOXG0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7db354e7-feee-4b3f-b1e4-2c132652a50e

The open-access MAF lists 17 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 4, Silent 3, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSPP | c.292A>G p.T98A | Missense Mutation (SNP) | VAF 116/333 reads (35%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.192); catalogued as rs1448500829; called by muse, mutect2, varscan2
- HELLS | c.2408G>A p.R803Q | Missense Mutation (SNP) | VAF 99/182 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53298487; called by muse, mutect2, varscan2
- JADE1 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 144/353 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs753231987, COSV56906955; called by muse, mutect2, varscan2
- NSUN7 | c.976G>C p.V326L | Missense Mutation (SNP) | VAF 65/392 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV57273156; called by muse, mutect2, varscan2
- TENM3 | c.7510G>A p.V2504I | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1168499456, COSV69305824; called by muse, mutect2, varscan2
- ANK2 | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 223/548 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1QTNF1 | c.170A>C p.H57P | Missense Mutation (SNP) | VAF 52/451 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FAT3 | c.9931G>C p.V3311L | Missense Mutation (SNP) | VAF 167/391 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- LSG1 | c.1442A>G p.H481R | Missense Mutation (SNP) | VAF 51/352 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CEP170B | c.2616G>A p.K872= (on ENST00000453495; = p.K801= on NM_015005.3) | Silent (SNP) | VAF 69/149 reads (46%) | called by muse, mutect2, varscan2
- EXOSC5 | c.51A>T p.T17= | Silent (SNP) | VAF 56/235 reads (24%) | called by muse, mutect2, varscan2
- NPAP1 | c.771G>A p.P257= | Silent (SNP) | VAF 171/380 reads (45%) | catalogued as rs774790100, COSV100276121; called by muse, mutect2, varscan2
- ABI3 | chr17:49210704 G>T | 5'Flank (SNP) | VAF 32/114 reads (28%) | called by muse, mutect2, varscan2
- CASP2 | c.967+99C>T | Intron (SNP) | VAF 87/655 reads (13%) | catalogued as COSV100131213; called by muse, mutect2, varscan2
- CSNK1A1 | c.124-57T>C | Intron (SNP) | VAF 34/179 reads (19%) | called by muse, mutect2, varscan2
- IDO2 | c.450-76G>A | Intron (SNP) | VAF 21/102 reads (21%) | catalogued as rs191755782; called by muse, mutect2, varscan2
- TCN2 | c.257+36A>G | Intron (SNP) | VAF 21/148 reads (14%) | catalogued as rs965238166; called by muse, mutect2, varscan2
